Somatic mutation profile of tumor specimen BA2870D (aliquot aq-BA2870D) from BEATAML1.0 case 2364, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with mutated NPM1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 77.4 years (28,257 days).
Specimen BA2870D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 886638a1-c55b-4324-8ce8-3c8b9bb17536.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2641D (Solid Tissue Normal), aliquot aq-BA2641D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/955380ed-fafd-42cc-b523-1292fe90fed2

The open-access MAF lists 23 somatic variants for this specimen: 19 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Frame Shift Ins 2, Silent 2, Frame Shift Del 1, Intron 1, 5'Flank 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NPM1 | c.860_863dup p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 18/72 reads (25%) | catalogued as rs587776806, COSV51548899, COSV51555098, COSV51559390, COSV51564309; ClinVar: pathogenic; called by pindel, varscan2
- ASPSCR1 | c.713C>A p.A238E | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated (0.77); PolyPhen benign (0.011); catalogued as COSV100144994; called by muse, mutect2
- CIART | c.693G>C p.K231N | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as COSV51746183; called by muse, mutect2
- CUX2 | c.2461G>A p.G821S | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); catalogued as COSV55627542; called by muse, mutect2, varscan2
- FLT3 | c.1471G>T p.V491L | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.077); catalogued as COSV54042664, COSV54046758; called by muse, mutect2
- HUNK | c.1678C>T p.R560C | Missense Mutation (SNP) | VAF 62/117 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.791); catalogued as rs145719858, COSV54227623; called by muse, mutect2, varscan2
- NGEF | c.979G>T p.V327F | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV50920276; called by muse, mutect2
- NPAS4 | c.968G>A p.R323H | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.395); catalogued as rs751922807, COSV104408273; called by muse, varscan2
- PDE10A | c.2360C>A p.S787Y | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.006); catalogued as rs1210428088; called by mutect2, varscan2
- ACTR3B | c.1205A>T p.E402V | Missense Mutation (SNP) | VAF 19/156 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BSN | c.9119C>A p.A3040D | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.092); called by muse, mutect2
- CCND3 | c.795_808del p.A266Pfs*53 | Frame Shift Del (DEL) | VAF 20/66 reads (30%) | called by mutect2, pindel
- IGHA2 | c.304C>T p.R102* | Nonsense Mutation (SNP) | VAF 9/25 reads (36%) | called by mutect2, varscan2
- KCNC2 | c.1844C>T p.S615F | Missense Mutation (SNP) | VAF 9/180 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.38); called by muse, mutect2
- ODC1 | c.1025A>C p.K342T | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.619); called by muse, mutect2, varscan2
- RNF6 | c.2026G>T p.V676F | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); called by muse, mutect2
- SPATA31E1 | c.179G>T p.S60I | Missense Mutation (SNP) | VAF 154/348 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, varscan2
- STAG2 | c.1587_1588dup p.R530Ifs*47 | Frame Shift Ins (INS) | VAF 21/70 reads (30%) | called by mutect2, pindel, varscan2
- TRIM32 | c.1409G>C p.S470T | Missense Mutation (SNP) | VAF 33/62 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- COL13A1 | c.690C>A p.R230= | Silent (SNP) | VAF 51/129 reads (40%) | called by muse, mutect2, varscan2
- NEMP1 | c.6G>T p.A2= | Silent (SNP) | VAF 5/59 reads (8%) | called by muse, mutect2
- AKR1C3 | c.369+34C>T | Intron (SNP) | VAF 12/87 reads (14%) | called by muse, varscan2
- SYCE1 | chr10:133567900 G>A | 5'Flank (SNP) | VAF 22/38 reads (58%) | catalogued as rs1424075426, COSV58215874; called by muse, mutect2
